Somatic mutation profile of tumor specimen TCGA-5P-A9JW-01A (aliquot TCGA-5P-A9JW-01A-11D-A42J-10) from TCGA case TCGA-5P-A9JW, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 64.5 years (23,570 days).
Specimen TCGA-5P-A9JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1ce6163-dd86-4780-a479-78cd2cfcb88d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9JW-10A (Blood Derived Normal), aliquot TCGA-5P-A9JW-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fba92737-0d7c-481b-a2fe-23fc360cb7d3

The open-access MAF lists 88 somatic variants for this specimen: 69 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 17, Frame Shift Del 9, Nonsense Mutation 6, In Frame Del 2, RNA 1, Nonstop Mutation 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.301T>C p.C101R (on ENST00000219054; = p.C22R on NM_001308169.2) | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376726292; called by muse, mutect2
- ACSM2B | c.301T>C p.C101R | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100312297, COSV61657951; called by muse, mutect2, varscan2
- AOC1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100710590; called by muse, mutect2, varscan2
- ARRDC2 | c.1130T>G p.I377S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99716562; called by muse, mutect2, varscan2
- ATP13A2 | c.644T>G p.I215S | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100453893; called by muse, mutect2, varscan2
- CAPN12 | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV99399745; called by muse, mutect2, varscan2
- CCDC14 | c.1313A>C p.E438A (on ENST00000488653; = p.E390A on NM_022757.5) | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100112941; called by muse, mutect2, varscan2
- CCDC148 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1258067047, COSV51754847; called by muse, mutect2, varscan2
- CCNB2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1225047849, COSV99878929; called by muse, mutect2, varscan2
- CD164 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99248677; called by muse, mutect2, varscan2
- CECR2 | c.920C>G p.S307C (on ENST00000342247 / NM_001290047.2; = p.S144C on NM_001290046.1) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99376928; called by muse, mutect2, varscan2
- CECR2 | c.2747G>T p.C916F (on ENST00000342247 / NM_001290047.2; = p.C733F on NM_001290046.1) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs1292384319, COSV99376935; called by muse, mutect2, varscan2
- CEP135 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV99954086; called by muse, mutect2, varscan2
- CFAP299 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.487); catalogued as COSV100811318, COSV63877096; called by muse, mutect2, varscan2
- CHD8 | c.4756T>A p.Y1586N (on ENST00000646647 / NM_001170629.2; = p.Y1307N on NM_020920.4) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100783787; called by muse, mutect2, varscan2
- CLSTN3 | c.2521A>T p.N841Y | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.091); catalogued as COSV99866494; called by muse, mutect2, varscan2
- DENND2C | c.1904C>T p.A635V (on ENST00000393274 / NM_001256404.2; = p.A578V on NM_198459.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67922158; called by muse, mutect2, varscan2
- EEA1 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100467024, COSV100467178; called by muse, mutect2, varscan2
- EFNA2 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99288914; called by muse, mutect2, varscan2
- ELF2 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99642522; called by muse, mutect2, varscan2
- EME2 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765401210, COSV99167654; called by muse, mutect2, varscan2
- ENTPD4 | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs773326250, COSV100652492; called by muse, mutect2, varscan2
- EPCAM | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV99764004; called by muse, mutect2, varscan2
- FOXA3 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99841358; called by muse, mutect2, varscan2
- GFRA2 | c.522C>A p.C174* | Nonsense Mutation (SNP) | VAF 57/158 reads (36%) | catalogued as COSV100151378; called by muse, mutect2, varscan2
- HERC1 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV101496309; called by muse, mutect2, varscan2
- HTR1A | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 60/202 reads (30%) | catalogued as COSV100108896, COSV100109021; called by muse, mutect2, varscan2
- HTR1A | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100108900; called by muse, mutect2, varscan2
- IQSEC1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1367258246, COSV99831283; called by muse, mutect2
- LRRC8A | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99396234; called by muse, mutect2, varscan2
- MUC16 | c.9400A>T p.T3134S | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV101198076; called by muse, mutect2, varscan2
- MXI1 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99491227; called by muse, mutect2, varscan2
- MYBL2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV53828995, COSV99405993; called by mutect2, varscan2
- MYLK | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100658488; called by muse, mutect2, varscan2
- NAP1L4 | c.1128A>C p.*376Yext*60 | Nonstop Mutation (SNP) | VAF 161/543 reads (30%) | catalogued as COSV101000642; called by muse, mutect2, varscan2
- NCOR2 | c.2957G>T p.R986L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as COSV100656811, COSV100657262; called by muse, mutect2, varscan2
- NDUFB9 | c.488T>A p.L163* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV52676291, COSV99412639; called by muse, mutect2, varscan2
- OGN | c.112T>C p.F38L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99363937; called by muse, mutect2, varscan2
- PANK1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100285493; called by muse, mutect2, varscan2
- PRTG | c.2399A>G p.D800G | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101221245; called by muse, mutect2, varscan2
- QTRT2 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1437614342, COSV55560617, COSV55561096; called by muse, mutect2, varscan2
- RGL1 | c.1474T>G p.Y492D (on ENST00000360851 / NM_001297672.2; = p.Y527D on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100486184; called by muse, mutect2, varscan2
- RPA2 | c.107A>C p.E36A | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100536045; called by muse, mutect2, varscan2
- SETMAR | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.02); catalogued as COSV100740826; called by muse, mutect2, varscan2
- SMC2 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV99658319; called by muse, mutect2, varscan2
- SMYD2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.794); catalogued as COSV100873104; called by muse, mutect2, varscan2
- SP3 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100021522; called by mutect2, varscan2
- STK17A | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100081983; called by muse, mutect2, varscan2
- STK26 | c.1221del p.Q408Kfs*32 | Frame Shift Del (DEL) | VAF 135/334 reads (40%) | catalogued as COSV53746350; called by pindel, varscan2
- TBC1D1 | c.3235A>T p.R1079* | Nonsense Mutation (SNP) | VAF 68/208 reads (33%) | catalogued as COSV99790433; called by muse, mutect2, varscan2
- TJP1 | c.4582A>G p.T1528A | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs1354132602, COSV100632293; called by muse, mutect2
- TRPV6 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100844114; called by muse, mutect2, varscan2
- USP32 | c.1503C>A p.N501K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.76); catalogued as COSV100341389; called by muse, mutect2, varscan2
- VRTN | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs779953247, COSV56439756; called by muse, mutect2, varscan2
- WDR17 | c.3568C>A p.Q1190K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as COSV99706740; called by muse, mutect2, varscan2
- ZNF135 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs754339491, COSV100536429, COSV100536440, COSV57881739; called by muse, mutect2, varscan2
- ZNF438 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100061209; called by muse, mutect2, varscan2
- ZNF831 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs756858166, COSV64042054; called by muse, mutect2, varscan2
- AHCTF1 | c.729del p.R244Afs*7 (on ENST00000366508; = p.R218Afs*7 on NM_015446.5) | Frame Shift Del (DEL) | VAF 49/228 reads (21%) | called by mutect2, pindel, varscan2
- GLB1L3 | c.209del p.T70Mfs*19 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | called by mutect2, pindel, varscan2
- LPL | c.374_376del p.A125del | In Frame Del (DEL) | VAF 46/151 reads (30%) | called by mutect2, pindel, varscan2
- MAN2A1 | c.2925del p.T976Qfs*9 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- NOS2 | c.1692_1701del p.F565Rfs*10 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- NPBWR2 | c.712_723del p.R238_A241del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- NR3C1 | c.1996_1997del p.M666Efs*11 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- PAN2 | c.348_363del p.S116Rfs*43 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- STAB1 | c.1576_1581delinsA p.L526Kfs*22 | Frame Shift Del (DEL) | VAF 52/171 reads (30%) | called by pindel, varscan2*
- TEFM | c.700dup p.T234Nfs*30 | Frame Shift Ins (INS) | VAF 53/189 reads (28%) | called by mutect2, pindel, varscan2
- VPS13C | c.6084del p.I2028Mfs*3 (on ENST00000644861 / NM_020821.3; = p.I1985Mfs*3 on NM_017684.5) | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- ACSM4 | c.1296C>T p.F432= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV101257007; called by muse, mutect2, varscan2
- CACNA1D | c.723C>A p.A241= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV99856549; called by muse, mutect2, varscan2
- CENPU | c.597C>T p.N199= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs992540337, COSV55658822; called by muse, mutect2, varscan2
- CGAS | c.231T>C p.T77= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV100943618; called by muse, mutect2, varscan2
- CHD8 | c.4755C>T p.Y1585= (on ENST00000646647 / NM_001170629.2; = p.Y1306= on NM_020920.4) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100783788; called by muse, mutect2, varscan2
- DNAH11 | c.2802A>T p.T934= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV100176961; called by muse, mutect2
- FLT4 | c.2491C>T p.L831= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs776853944, COSV99985862; called by muse, mutect2, varscan2
- GSPT1 | c.792T>C p.L264= (on ENST00000420576 / NM_001130007.2; = p.L402= on NM_002094.4) | Silent (SNP) | VAF 54/234 reads (23%) | catalogued as COSV101341690; called by muse, mutect2, varscan2
- METTL17 | c.903T>A p.A301= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV100068450; called by muse, mutect2, varscan2
- NDUFA10 | c.579C>T p.V193= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV99401129; called by muse, mutect2, varscan2
- NEU1 | c.165G>A p.Q55= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99998577; called by muse, mutect2, varscan2
- PCLO | c.14229C>T p.V4743= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV100427240; called by muse, mutect2, varscan2
- PKHD1 | c.4770C>G p.L1590= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100580976; called by muse, mutect2, varscan2
- SEMA5A | c.2709G>C p.S903= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV101227032; called by muse, mutect2, varscan2
- SEPTIN8 | c.420C>A p.R140= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV99736009; called by muse, mutect2, varscan2
- TAS1R2 | c.219G>A p.Q73= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100946132; called by muse, mutect2
- WDHD1 | c.1800A>G p.G600= | Silent (SNP) | VAF 159/469 reads (34%) | catalogued as COSV100777532; called by muse, mutect2, varscan2
- H3-3B | chr17:75784754 A>G | 5'Flank (SNP) | VAF 42/124 reads (34%) | catalogued as COSV99504468; called by muse, mutect2, varscan2
- LINC02872 | n.224C>G | RNA (SNP) | VAF 72/239 reads (30%) | called by muse, mutect2, varscan2
